Somatic mutation profile of tumor specimen TCGA-AB-2865-03B (aliquot TCGA-AB-2865-03B-01W-0728-08) from TCGA case TCGA-AB-2865, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia without maturation; Tissue or organ of origin: Bone marrow; Age at diagnosis: 75.3 years (27,486 days).
Specimen TCGA-AB-2865-03B: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 41f3b7f5-f00d-46c3-8907-df14e1e7566a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AB-2865-11B (Solid Tissue Normal), aliquot TCGA-AB-2865-11B-01W-0729-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/32fe6526-7dc6-4d52-85ee-291e6030a5d4

The open-access MAF lists 4 somatic variants for this specimen: 1 protein-altering or splice-affecting, 3 silent.
By variant classification: Silent 3, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BBX | c.2088del p.K696Nfs*270 (on ENST00000325805 / NM_001142568.3; = p.K696Nfs*240 on NM_020235.7) | Frame Shift Del (DEL) | VAF 85/184 reads (46%) | called by mutect2, varscan2
- ATP2B3 | c.2703G>A p.T901= | Silent (SNP) | VAF 26/28 reads (93%) | catalogued as rs782020723, COSV54843363; called by muse, mutect2, varscan2
- MYOM3 | c.4179C>T p.T1393= | Silent (SNP) | VAF 39/96 reads (41%) | catalogued as COSV58396276; called by muse, mutect2, varscan2
- SLC26A3 | c.387G>A p.P129= | Silent (SNP) | VAF 73/171 reads (43%) | catalogued as rs754233296, COSV60641088; called by muse, mutect2, varscan2
